Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A1O8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A1O8-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrioid C54.1 2/24/11 *lw*

Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

A. Uterus, bilateral ovaries and fallopian tubes;
hysterectomy and
bilateral salpingo-oophorectomy: FIGO grade III (of III)
endometrial adenocarcinoma, endometrioid type, is
identified forming
a mass (3.6 x 2.5 x 2.2 cm) located in the anterior and
lateral
uterine wall. The tumor invades 1.7 cm into the
myometrium (total
wall thickness 2.0 cm). The tumor does not involve the
endocervix.
Lymphovascular space invasion is identified. There are
multiple
intramural leiomyomata ranging in size from 0.3 cm to 0.7
cm in
greatest dimension. The bilateral ovaries and fallopian
tubes are
atrophic and not involved.

B. Lymph node, right pelvic, biopsy: A single right
pelvic lymph
node is positive for metastatic carcinoma consistent with
endometrial primary.

C. Lymph nodes, left pelvic, biopsy: Multiple (2) left
pelvic
lymph nodes are positive for metastatic carcinoma
consistent with
endometrial primary.

With available surgical materials, [AJCC pT1bN1] (7th
edition,
2010).

This final pathology report is based on the
gross/macrosopic

HI/PA Discrepancy		

[page 2 of 2]
examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, bilateral fallopian tubes and ovaries" is a 100.0 gram uterus with attached bilateral tubes and ovaries. The uterine serosa is smooth. There is a 3.6 x 2.5 x 2.2 cm exophytic mass in the anterior and lateral walls of the endometrial cavity, grossly invading 1.7 cm into a thick myometrium.

There are multiple intramural leiomyomas, ranging in size from 0.3

cm to 0.7 cm. There is a 2.5 x 0.8 x 0.6 cm right ovary with a

smooth outer surface and a solid cut surface with a 5.7 x 0.5 cm

right fallopian tube which is unremarkable. There is a 2.6 x 1.4 x

0.6 cm left ovary with a smooth outer surface and a solid cut

surface with a 5.5 x 0.7 cm left fallopian tube which is unremarkable. Representative sections submitted.

B. Received fresh labeled "right pelvic nodes" is a 2.6 x 1.8 x 1.7

cm aggregate of adipose and lymphatic tissue. Lymph nodes all

submitted.

C. Received fresh labeled "left pelvic nodes" is a 3.1 x 1.5 x 1.2

cm aggregate of adipose and lymphatic tissue. Lymph nodes all

submitted.

Source: NCI Genomic Data Commons file 09879f18-76b0-495b-a3eb-c583d89e35e2 (TCGA-D1-A1O8.8E7FDFD5-892F-4671-8172-FC2BFB800AE9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).